Surgical pathology report (de-identified scan), TCGA case TCGA-KN-8427, project TCGA-KICH (Kidney Chromophobe), tissue source site Harvard, specimen TCGA-KN-8427-01A (Primary Tumor).

[page 1 of 2]
PATHOLOGIC DIAGNOSIS:

SPECIMEN DESIGNATED "LEFT RADICAL NEPHRECTOMY":

RENAL CELL CARCINOMA, high grade with chromophobe and sarcomatoid features, and necrosis (16.5 cm), Fuhrman nuclear grade IV of IV.
Tumor extensively invades into the perinephric adipose tissue and focally through Gerota's fascia.
Tumor is present at the inked Gerota's fascial margin and renal vein margin.
Renal artery and ureter margins are negative for tumor.
Lymphovascular invasion and venous invasion are present.
Adrenal gland, negative for tumor.
AJCC Classification: T4 Nx Mx.

NOTE:

Dr. R. Welch, GU Pathology Service, has reviewed this case and concurs.

RENAL PATHOLOGY EVALUATION OF KIDNEY PARENCHYMA:

LEFT KIDNEY, NEPHRECTOMY:

MINIMAL CHRONIC CHANGES OF THE KIDNEY PARENCHYMA, MOST
LIKELY AGE-RELATED (SEE NOTE)

ARTERIAL AND ARTERIOLAR SCLEROSIS, MILD (SEE NOTE)

NOTE:

The kidney parenchyma examined shows minimal chronic changes. There is mild focal global glomerulosclerosis (3.0% of glomeruli), mild tubular atrophy and interstitial fibrosis (less than 10% of the parenchyma), and a mild degree of vascular sclerosis.

MICROSCOPIC DESCRIPTION:

Sections of formalin-fixed, paraffin embedded tissue (block A13) were evaluated using HE, PAS, Jones silver methenamine, and APOC (trichrome) stains. The sample consists of cortex and medulla. There are 149 glomeruli present, of which 13 (8.7%) are globally sclerosed. The remaining glomeruli show mild expansion of the mesangial areas. There are rare cysts and focal double contours of the glomerular basement membranes. Rare distal tubules contain PAS positive hyaline casts. Less than 10% of the cortical parenchyma shows tubular atrophy and interstitial fibrosis. Arteries and arterioles exhibit a mild degree of sclerosis of the media and of the intima.

CLINICAL DATA:

History: None given.

Operation: L radical nephrectomy, regional lymph node dissection.

Operative Findings: None given.

Clinical Diagnosis: Renal cell CA.

TISSUE SUBMITTED:

A13: L renal mass block.

GROSS DESCRIPTION:

[page 2 of 2]
Pathology Report

The specimen is received fresh, labeled with the patient's name, unit number, and "1. Left kidney", and consists of a 2,497 gm left nephrectomy specimen, measuring 26.5 x 12.5 x 12.5 cm overall and including the left kidney (16 x 11 x 12 cm), left adrenal gland (7.6 x 1.4 x 1.0 cm), and surrounding perirenal fat, measuring up to 6.8 cm in greatest dimension. Extending from the renal pelvis is a ureter (1.8 cm in length x 0.8 cm in diameter), possible renal vein (7.4 cm in length x 0.3 cm in diameter, focally disrupted) and possible renal artery (1.5 cm in length x 0.2 cm in diameter). There is a 16.5 x 12.5 x 2.5 cm tan/pink/red/yellow heterogeneous mass with multiple areas of necrosis and hemorrhage, encompassing almost the entire kidney with satellite nodules (at least three) in the surrounding perirenal fat, ranging from 2.5 to 5.0 cm and extending to the inked margin and Gerota's fascia. There is a 1.5 x 0.5 x 0.5 cm tan/red nodule in the ureter. The tumor is 1.5 cm from the ureter, 3.0 cm from the arterial, and 7.5 cm from the vein margins. The tumor markedly compressed the surrounding renal parenchyma, which contains multiple tan/pink/red satellite nodules. The corticomedullary junction is diffusely blurred with satellite tumor nodules distending the caliceal spaces. The adrenal gland appears grossly unremarkable. Representative sections of the tumor are submitted for cytogenetics, Quick Fix, and Tissue Bank, and representative sections of normal kidney tissue are submitted to the Tissue Bank and for electron microscopy and immunofluorescent studies. Four possible small lymph nodes are identified in the perirenal fat.

Micro A1: Tumor nodules in perirenal fat and inked deep margin/Gerota's fascia, 2 frags, RBS.
Micro A2: Tumor nodule in perirenal fat to inked margin and Gerota's fascia, 1 frag, [redacted]
Micro A3: Tumor to kidney capsule and inked margin, 2 frags, [redacted]
Micro A4: Tumor to kidney, kidney capsule, and tumor nodule in perirenal fat, 1 frag, RBS.
Micro A5: Tumor in calyx and tumor within ureter, 2 frags, [redacted]
Micro A6: Tumor to normal kidney, 2 frags, [redacted]
Micro A7: Tumor to renal vein and pelvis, 1 frag, [redacted]
Micro A8: Renal vein, artery and ureteral margins, 3 frags, [redacted]
Micro A9-A12: T1 through T4 (RBS tumor), 5 frags, [redacted]
Micro A13: Normal kidney, 1 frag, [redacted]
Micro A14: Representative sections of adrenal gland, 2 frags, [redacted]
Micro A15: Small lymph nodes in perirenal fat, 4 frags, [redacted]

By his/her signature below, the senior physician certifies that he/she personally conducted a macroscopic examination (gross only) exam if so stated, of the described specimen(s) and rendered or confirmed the diagnosis(es) related thereto.

Source: NCI Genomic Data Commons file 81a1bc8a-4a14-4268-960f-aacfab9d6593 (TCGA-KN-8427.F2A42C36-A475-43C7-BCD1-48B83C3AB5A6.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).